Gene-level copy-number profile of tumor specimen TCGA-2Y-A9H1-01A from TCGA case TCGA-2Y-A9H1, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 58.1 years (21,222 days).
Specimen TCGA-2Y-A9H1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.787422da-8cd1-4484-a181-e001ea20ca6a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2Y-A9H1-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bf7d6db8-f322-4e1f-8783-e7294195e7c9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 4,788; copy number 2: 46,775; copy number 3: 6,473; copy number 4: 228; copy number 5: 92; copy number 6: 3; copy number 8: 208; copy number 9: 93; copy number 10: 26; copy number 11: 1,129.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2Y-A9H1-01A-11D-A381-01): tumor purity 0.73, ploidy 2.29, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,551 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:10,199,823–10,295,579, 8 genes, copy number 5: AC006499.1, AC006499.8, RAF1P1, AC006499.4, AC006499.2, AC006499.3, AC006499.5, AC006499.7.
- chr4:77,216,416–77,216,878, 1 gene, copy number 6: AC008638.3.
- chr5:74,084,068–74,536,976, 6 genes, copy number 5 (within-gene range 3–5): LINC02122, LINC01331, LINC01335, RN7SL814P, LINC01333, LINC01332.
- chr5:155,397,291–155,493,598, 2 genes, copy number 6: AC010591.1, AC008725.1.
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 5–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,406. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
